Surgical pathology report (de-identified scan), TCGA case TCGA-DG-A2KM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-DG-A2KM-01A (Primary Tumor).

Sample Type TUMOUR

Sample Preparation
Site of Primary (Event)
Site of Tissue
Year of Sample Collection
Age at Sample Collection (yrs)
Sample Comments
Days to Procedure Date
Days to Diagnosis
Type of Procedure
Site of Primary (Histology)
Bilateral Disease
Tumour Size (cm)
Histology
Grade/Differentiation
Pathological T
Pathological N
Number of Nodes Sampled
Number of Nodes Positive
Clinical M
Histology Comments

Fresh Frozen
Cervical
12:00 position - cervix
0
28
Surgical resection
Cervix
NO
2.7000000000000002
Squamous cell carcinoma, NOS
Grade II (Moderately differentiated)
T1b
N1
4
10
M1

1CD-0-3
Carcinoma, squamous cell, NOS
8070/3
Site: cervix, NOS C53.9
8/23/11

Source: NCI Genomic Data Commons file fe1c1c8a-5ad2-47dc-9030-3a50282c1413 (TCGA-DG-A2KM.CDF128FF-AEED-450F-B882-09A020F3DB36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).